Gene-level copy-number profile of tumor specimen TCGA-55-6712-01A from TCGA case TCGA-55-6712, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA.
Specimen TCGA-55-6712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fc8c9e67-6bf0-482c-8863-f8b6c18b4663.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6712-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f82ae2a0-1fd3-4e6a-9863-68bb08459987

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 2,341; copy number 2: 15,147; copy number 3: 25,398; copy number 4: 11,849; copy number 5: 2,858; copy number 6: 1,575; copy number 7: 344; copy number 8: 179; copy number 9: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6712-01A-11D-1854-01): tumor purity 0.29, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,532,145–10,620,420, 2 genes: AL135790.2, PTPRD-AS2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 555 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:8,207,019–8,572,206, 11 genes, copy number 7: AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3.
- chr7:70,972–7,566,996, 185 genes, copy number 7 (broad region; genes not listed).
- chr12:76,562,294–78,213,010, 17 genes, copy number 7 (within-gene range 4–7): AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1.
- chr14:45,203,190–55,272,075, 179 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:74,498,183–79,974,169, 124 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:50,693,198–50,707,914, 1 gene, copy number 9 (within-gene range 5–9): ANKRD40.
- chr17:50,719,565–53,106,358, 34 genes, copy number 7–9: LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40.
- chr17:53,353,427–53,682,111, 4 genes, copy number 7: AC005341.1, AC090079.1, AC090079.2, AC034268.1.

Autosomal genes at a single copy (total copy number 1): 2,341. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
